Surgical pathology report (de-identified scan), TCGA case TCGA-BB-A6UM, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-A6UM-01A (Primary Tumor).

- LAB RESULTS

SURG PATH REPORT
COLLECTION DATE/TIME:

PATH#:

1st Specimen collected on
Accessioned on

FINAL DIAGNOSIS ----- Pathologist:

1) LEFT TONSIL (TONSILLECTOMY): HPV RELATED INFILTRATING SQUAMOUS
CELL CARCINOMA (2.4 CM). TUMOR FOCALLY EXTENDS TO THE INKED
RESECTION MARGIN. AREAS HIGHLY SUSPICIOUS FOR ANGIOLYMPHATIC
INVASION. SEE NOTE.

NOTE: The tumor is positive for p16 and HPV16.

2) RIGHT TONSIL (TONSILLECTOMY): TONSILLAR TISSUE. NEGATIVE FOR
TUMOR.

See

for official report.

Reported by:

Final Report Signed on

ICD-O-3

Carcinoma, squamous
cell NOS 8070/3

Site ① Tonsil NOS C09.9

7/24/13

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:

Source: NCI Genomic Data Commons file b0f90973-9d3e-4ab0-8fdd-980aea81e22b (TCGA-BB-A6UM.CE88FA18-1E39-4D55-AD46-7F3213236050.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).